Gene-level copy-number profile of specimen HCM-BROD-0568-C15-85M from HCMI case HCM-BROD-0568-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 63.8 years (23,288 days).
Specimen HCM-BROD-0568-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 35508be7-61f4-4ed9-a6ee-ea8afd7be391.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0568-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/0214f45e-8a1c-4ed2-beff-5726c14a121f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 909; copy number 2: 10,826; copy number 3: 27,139; copy number 4: 11,080; copy number 5: 3,778; copy number 6: 3,462; copy number 7: 391; copy number 8: 208; copy number 9: 73; copy number 10: 68; copy number 11: 223; copy number 12: 28; copy number 13: 8; copy number 14: 38; copy number 15: 1; copy number 16: 3; copy number 18: 52; copy number 28: 2; copy number 29: 50; copy number 30: 1; copy number 33: 49.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,049 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:110,082,688–110,109,719, 1 gene, copy number 7: LINC01397.
- chr1:143,419,625–143,500,512, 5 genes, copy number 11–16: AC239859.5, RNA5SP533, AC239859.3, AC239859.2, LINC02799.
- chr5:767,382–997,308, 9 genes, copy number 7: BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1.
- chr5:1,594,626–1,634,005, 4 genes, copy number 7: AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr5:10,352,701–10,440,388, 2 genes, copy number 7: AC012640.2, MARCHF6.
- chr5:13,637,919–13,638,381, 1 gene, copy number 7: AC016546.1.
- chr5:26,382,519–26,399,819, 1 gene, copy number 7: AC025475.1.
- chr7:87,109,539–87,713,323, 13 genes, copy number 7 (within-gene range 6–7): AC004023.1, AC005076.1, DMTF1, AC005076.2, TMEM243, Y_RNA, TP53TG1, AC005045.1, AC005045.2, CROT, ABCB4, ABCB1, HNRNPA1P9.
- chr7:87,934,143–88,202,889, 1 gene, copy number 7: ADAM22.
- chr7:89,882,353–117,323,152, 544 genes, copy number 7–18 (broad region; genes not listed).
- chr7:140,997,952–141,015,228, 2 genes, copy number 7: CCT4P1, MRPS33.
- chr8:144,713,899–145,066,685, 18 genes, copy number 7: AF186192.3, ZNF251, ZNF34, RN7SL395P, RPL8, MIR6850, ZNF517, ZNF7, COMMD5, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr11:34,853,094–40,112,599, 49 genes, copy number 33: APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1, COMMD9, PRR5L, AC087277.1, AC087277.2, AC009656.1, TRAF6, AC061999.1, RAG1, RAG2, IFTAP, AC104042.1, AC061997.1, RPL7AP56, LINC02760, AC103798.1, LRRC6P1, AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1.
- chr16:7,726,841–22,613,483, 399 genes, copy number 7–30 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 909. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
